Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A3X6, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A3X6-01A (Primary Tumor).

Procurement Date Laterality:

Path Report: BLADDER TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Bladder

Tumor size: 3 x 2.5 x 4 cm

Tumor features: None specified

Histologic type: Transitional cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Muscularis propria

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-o-3
carcinoma, urothelial, NOS
8120/3

Site:
path: bladder, NOS
C67.9

C67.2
C67.2
bladder, wall, lateral

5-17-12 RD

Reviewed Initials	5/10/12	

Source: NCI Genomic Data Commons file f67c97ab-48f6-40bd-9d2e-a16db50fadfc (TCGA-E7-A3X6.BC75580D-4F4D-408C-9E9C-116A260DDED3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).